Somatic mutation profile of tumor specimen BA2007D (aliquot aq-BA2007D) from BEATAML1.0 case 2071, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.3 years (26,043 days).
Specimen BA2007D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be13733c-533e-43db-8197-1bc230dbcd85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2717D (Solid Tissue Normal), aliquot aq-BA2717D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f173b122-d57f-466b-92e1-5346aceee329

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Nonsense Mutation 1, 3'UTR 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1784_1804dup p.R595_L601dup | In Frame Ins (INS) | VAF 47/114 reads (41%) | hotspot (GDC flag); catalogued as COSV54048674, COSV54065960, COSV54066688, COSV54076929; called by mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 27/97 reads (28%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CARD14 | c.2968G>A p.A990T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs575494155; called by muse, varscan2
- L1TD1 | c.2233C>T p.R745* | Nonsense Mutation (SNP) | VAF 43/124 reads (35%) | catalogued as rs890204634, COSV63133191; called by muse, mutect2, varscan2
- MROH1 | c.4112G>A p.R1371H | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs898597007; called by muse, mutect2, varscan2
- USH2A | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 83/248 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.138); catalogued as rs754523763, COSV56403480; called by muse, mutect2, varscan2
- CDKL2 | c.839A>G p.E280G | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.214); called by muse, varscan2
- PCDHGA9 | c.1590G>T p.M530I | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PVR | c.388C>A p.Q130K | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.986); called by muse, mutect2
- ATP10A | c.4458C>T p.D1486= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs760720206, COSV63519590, COSV63526293; called by muse, mutect2, varscan2
- INAVA | c.297C>A p.I99= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as COSV100949890; called by muse, mutect2
- KCNMB2 | c.*264G>A | 3'UTR (SNP) | VAF 47/134 reads (35%) | catalogued as rs762022056; called by muse, mutect2, varscan2
